TCGA case TCGA-DX-A8BT — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eea7d707-aeb9-4d00-ab5e-c1ea608517e9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Alive.

Diagnoses (2)
1. Malignant fibrous histiocytoma (the primary disease): ICD-O-3 morphology code: 8830/3; ICD-10 code: C49.3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of thorax; Classification of tumor: primary; Age at diagnosis: 63.5 years (23,204 days); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4.1; Tumor length measurement: 9.5; Tumor width measurement: 8.4.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No; Tumor depth descriptor: Deep.
2. Recurrence of diagnosis 1 (Malignant fibrous histiocytoma), site: Thorax, NOS. Age at diagnosis: 65.4 years (23,872 days); Days to diagnosis: 668 days (1.8 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.5; Tumor length measurement: 4.5; Tumor width measurement: 3.1.

Follow-up (4 entries)
- Day 668 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 668 days (1.8 years).
- Days to follow up: 811 days (2.2 years); Disease response: Tumor Free.
- Days to follow up: 1,081 days (3.0 years); Disease response: Tumor Free.
- Days to follow up: 1,230 days (3.4 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A8BT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,320 mg.
  Slide TCGA-DX-A8BT-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 19; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-DX-A8BT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A8BT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Pleomorphic 'MFH' / Undifferentiated pleomorphic sarcoma; Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Upper Extremity - Shoulder/axilla.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 697; Days from index date to pharmaceutical treatment ended: 773; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 697; Days from index date to pharmaceutical treatment ended: 773; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Radiation treatment: Days from index date to radiation therapy started: 63; Days from index date to radiation therapy ended: 112; Radiation therapy type: External; Radiation total dose: 6300; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 35; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,230 days; disease-specific survival: no event (censored), 1,230 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 668 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A8BT-01A-11D-A37B-01): tumor purity 0.64, ploidy 2.02, whole-genome doublings 1.
